Gene-level copy-number profile of tumor specimen TCGA-VS-A9UC-01A from TCGA case TCGA-VS-A9UC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 32.3 years (11,790 days).
Specimen TCGA-VS-A9UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.7b859eb2-0c1a-41f4-80af-d84d6e50099a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5459da9-e43a-42a8-8b5c-a36545fbeebd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,110; copy number 2: 44,884; copy number 3: 8,222; copy number 4: 3,438; copy number 5: 79; copy number 7: 16; copy number 10: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UC-01A-11D-A42N-01): tumor purity 0.72, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 166 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:170,173,865–174,160,165, 88 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:174,367,105–174,368,039, 1 gene, copy number 7: AL022400.1.
- chr5:16,661,907–21,779,522, 77 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
